Somatic mutation profile of tumor specimen MMRF_2326_1_BM_CD138pos (aliquot MMRF_2326_1_BM_CD138pos_T3_KHS5U_K14011) from MMRF case MMRF_2326, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,347 days).
Specimen MMRF_2326_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a1f5f72-d9c0-4cee-b69a-5e9baea6f665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2326_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2326_1_PB_Whole_C3_KHS5U_K14010; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25100fd-eb22-483c-9bb2-26257a6f4049

The open-access MAF lists 149 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 25, Silent 22, Intron 19, 3'Flank 7, Nonsense Mutation 5, Splice Region 5, 5'Flank 4, 5'UTR 3, Splice Site 3, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as COSV53246396; called by muse, mutect2, varscan2
- C4orf17 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1486473608; called by muse, mutect2
- DDX3X | c.676+2T>A p.X226_splice (on ENST00000399959; = p.X227_splice on NM_001356.5) | Splice Site (SNP) | VAF 31/39 reads (79%) | catalogued as COSV104433600; called by muse, mutect2, varscan2
- FAT3 | c.7319C>T p.T2440M | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs557022725, COSV53147401; called by muse, mutect2, varscan2
- FGF3 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376445217; called by muse, mutect2, varscan2
- GUCA2A | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs200135624; called by muse, mutect2, varscan2
- IGHV2-70 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs370734838; called by muse, varscan2
- IGHV2-70 | c.225T>A p.D75E | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs373801344; called by muse, varscan2
- IGHV2-70 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 62/104 reads (60%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs375052259; called by muse, varscan2
- IGHV2-70 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs371094987; called by muse, varscan2
- IGLV3-25 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs549600127; called by muse, mutect2, varscan2
- MCHR2 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56000362; called by muse, mutect2
- MGAM | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs758260512, COSV72074630; called by muse, mutect2, varscan2
- MRPS30 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101539272; called by muse, mutect2, varscan2
- NKAIN3 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100133871; called by muse, mutect2, varscan2
- PPIL4 | c.1120T>A p.S374T | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV53568072; called by muse, mutect2, varscan2
- PTPRT | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV62011906; called by muse, mutect2, varscan2
- RIPOR2 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147575554; called by muse, mutect2
- SCN1A | c.3703C>T p.L1235= (on ENST00000303395 / NM_001202435.3; = p.L1224= on NM_006920.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 59/189 reads (31%) | catalogued as COSV57676529; called by muse, mutect2, varscan2
- SLC17A1 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV99765685; called by muse, mutect2
- SLC7A6 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1389121218; called by muse, mutect2, varscan2
- SSBP3 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1332724257, COSV58885239; called by muse, mutect2, varscan2
- UBE3A | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99216568; called by muse, mutect2, varscan2
- UBL5 | c.177C>G p.D59E | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs767282164; called by muse, mutect2, varscan2
- USP9X | c.7245G>A p.W2415* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV61074211; called by muse, mutect2
- ZNF208 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.333); catalogued as rs1239173802, COSV68103400; called by muse, mutect2
- ADIPOR1 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AHNAK | c.8454G>T p.W2818C | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- ANO5 | c.2405_2407del p.I802del | In Frame Del (DEL) | VAF 24/78 reads (31%) | called by pindel, varscan2
- ASAP2 | c.2726G>A p.R909K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- C2orf78 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCDC88A | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CCDC97 | c.977A>C p.Y326S | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH24 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, varscan2
- CLCN1 | c.2192T>A p.L731H | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDND2 | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CYP4B1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CYRIB | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by muse, varscan2
- DELE1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, mutect2
- DISC1 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.041); called by muse, mutect2
- DUSP13 | c.*7A>C | Splice Region (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2
- EXOSC8 | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAT2 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC11 | c.725T>A p.L242* | Nonsense Mutation (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- FZD8 | c.1585C>G p.L529V | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GATAD2A | c.1568_1575+5del p.X523_splice | Splice Site (DEL) | VAF 53/132 reads (40%) | called by mutect2, pindel, varscan2
- GOT2 | c.1028A>T p.E343V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- IGHA1 | c.667+1G>A p.X223_splice | Splice Site (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ING5 | c.48C>G p.N16K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MARCKS | c.102G>A p.Q34= | Splice Region (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- MYO16 | c.2579G>A p.W860* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- NAV3 | c.3035C>T p.T1012I | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PFDN2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 112/160 reads (70%) | called by muse, mutect2, varscan2
- PLCH2 | c.3529A>C p.M1177L | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- PTGS2 | c.1660A>T p.I554F | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.041); called by muse, mutect2
- RAB14 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- RRP12 | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- SF3A2 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SLC9C2 | c.3220G>C p.E1074Q | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.36); called by muse, mutect2
- SNX4 | c.1074G>T p.M358I | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- TPT1 | c.293+2dup | Splice Region (INS) | VAF 33/55 reads (60%) | called by mutect2, pindel, varscan2
- TPT1 | c.102+3G>T | Splice Region (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- TRANK1 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2
- VWA1 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- WNK4 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZCWPW1 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 141/269 reads (52%) | called by muse, mutect2, varscan2
- ADRA1B | c.912C>T p.I304= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- ATF4 | c.996G>A p.Q332= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.3315C>T p.D1105= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs969722723, COSV63951637; called by muse, mutect2
- CYP2C19 | c.1140C>T p.L380= | Silent (SNP) | VAF 73/217 reads (34%) | catalogued as rs868401281, COSV64909336; called by muse, mutect2, varscan2
- ESPNL | c.2214G>A p.K738= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV58039816; called by muse, mutect2
- FBN3 | c.5760C>T p.L1920= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- FES | c.1578C>T p.L526= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- GNPTAB | c.1119T>G p.V373= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- GPR107 | c.996G>A p.V332= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs1452516893; called by muse, mutect2, varscan2
- HSPA5 | c.258C>T p.S86= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs149203266; called by muse, mutect2, varscan2
- IGHV2-70 | c.138C>T p.F46= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs374979633; called by muse, varscan2
- IL36RN | c.126C>T p.I42= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1317C>T p.I439= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs577502132, COSV69139109; called by muse, mutect2
- MYO15A | c.8043C>T p.F2681= | Silent (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- NAE1 | c.1515C>T p.V505= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2
- PLXNA2 | c.4143C>T p.R1381= | Silent (SNP) | VAF 38/282 reads (13%) | catalogued as rs780920790, COSV100886031; called by muse, mutect2, varscan2
- PLXNA4 | c.4008G>A p.R1336= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV58123253; called by muse, mutect2, varscan2
- RNGTT | c.267T>C p.L89= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- SBF2 | c.924C>G p.L308= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- SDC2 | c.426G>A p.R142= | Silent (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- SYPL1 | c.222T>C p.V74= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- TRPM2 | c.1479C>A p.I493= | Silent (SNP) | VAF 61/181 reads (34%) | called by muse, mutect2, varscan2
- ABCB9 | chr12:122980031 T>C | 5'Flank (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- ABCG4 | chr11:119161948 C>T | 3'Flank (SNP) | VAF 32/115 reads (28%) | catalogued as rs1238909569; called by muse, mutect2, varscan2
- ABHD6 | c.*589G>A | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- ATP8A2 | c.*1411T>G | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- ATP8A2 | c.*5611A>T | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- BLNK | c.*132A>G | 3'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948602 T>C | 3'Flank (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- CCNT2 | c.*2990C>T | 3'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs967838391; called by muse, mutect2
- CRB1 | c.3878+1679T>A | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as rs1358049208; called by muse, mutect2, varscan2
- DCUN1D3 | c.*1575C>G | 3'UTR (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- DDX55 | c.1165-257C>T | Intron (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2, varscan2
- DDX60L | c.*237A>G | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- DMD | c.31+83050T>A | Intron (SNP) | VAF 28/121 reads (23%) | catalogued as COSV55859184; called by muse, mutect2, varscan2
- EPHB2 | c.2956-9C>T | Intron (SNP) | VAF 78/180 reads (43%) | catalogued as rs1222969030, COSV101007539; called by muse, mutect2, varscan2
- EVA1B | chr1:36328179 G>A | 5'Flank (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- EYS | c.1766+3412T>A | Intron (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- FIGN | c.*29G>A | 3'UTR (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- GABRA4 | c.*673T>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- GABRA5 | c.87-37A>G | Intron (SNP) | VAF 121/219 reads (55%) | called by muse, mutect2, varscan2
- H2BC10 | c.*9C>T | 3'UTR (SNP) | VAF 20/123 reads (16%) | catalogued as rs762072729; called by muse, mutect2, varscan2
- HNRNPU | c.-137C>T | 5'UTR (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- HPSE2 | c.1614-2011G>C | Intron (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- IGLC3 | c.*37G>C | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- IKZF2 | c.*191A>C | 3'UTR (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- JAM2 | c.822-805C>G | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- KCNJ1 | chr11:128838707 T>A | 3'Flank (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- LAMP3 | c.-78C>A | 5'UTR (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- LMO7 | c.322-97A>T | Intron (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- MAP1LC3B | chr16:87391915 G>C | 5'Flank (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- NEU4 | c.*351C>T | 3'UTR (SNP) | VAF 32/87 reads (37%) | catalogued as rs778871296; called by muse, mutect2, varscan2
- NOS1AP | c.940-348G>A | Intron (SNP) | VAF 36/65 reads (55%) | catalogued as rs866076467; called by muse, mutect2, varscan2
- NUP43 | c.-23T>C | 5'UTR (SNP) | VAF 76/206 reads (37%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-9824A>T | Intron (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- OSBPL11 | c.*1054T>G | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, varscan2
- PITX2 | c.390+894T>C | Intron (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- POFUT2 | c.1136+736A>C | Intron (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1697+89A>T | Intron (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- PRPF4BP1 | n.105C>G | RNA (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- PTPRB | c.4060+12T>C | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- RALGDS | c.*652C>T | 3'UTR (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- RPS3 | c.31-284_31-282delinsT | Intron (DEL) | VAF 28/56 reads (50%) | called by pindel, varscan2*
- RSPO1 | c.*1092G>T | 3'UTR (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- SCFD2 | c.*390G>A | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- SERP1 | c.160+117A>G | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- SLC16A7 | c.*1638A>T | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- SPOCK3 | c.1-96G>T | Intron (SNP) | VAF 31/62 reads (50%) | catalogued as rs981135258; called by muse, mutect2, varscan2
- STC1 | c.*2246G>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- STMN4 | chr8:27236043 T>C | 3'Flank (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- SYNPO2L | c.*1762A>C | 3'UTR (SNP) | VAF 23/320 reads (7%) | called by muse, mutect2
- TBX2 | chr17:61412414 G>A | 3'Flank (SNP) | VAF 102/248 reads (41%) | catalogued as rs377741633; called by muse, mutect2, varscan2
- TRA2A | c.*447G>T | 3'UTR (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231219848 G>A | 3'Flank (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.*1882G>C | 3'UTR (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- VANGL1 | c.*6414G>A | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- ZAP70 | c.402+213G>A | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ZBTB37 | chr1:173866677 G>A | 5'Flank (SNP) | VAF 201/305 reads (66%) | called by muse, mutect2, varscan2
- ZBTB43 | chr9:126837721 del GTTT | 3'Flank (DEL) | VAF 38/131 reads (29%) | catalogued as rs1260661292; called by pindel, varscan2
- ZNF148 | c.*5468A>C | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- ZNF660 | c.*4194G>T | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
